Somatic mutation profile of tumor specimen TCGA-4E-A92E-01A (aliquot TCGA-4E-A92E-01A-11D-A37N-09) from TCGA case TCGA-4E-A92E, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 54.3 years (19,818 days).
Specimen TCGA-4E-A92E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34db4c06-1f12-45d5-816f-ab01d6653d30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4E-A92E-10A (Blood Derived Normal), aliquot TCGA-4E-A92E-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b4245b1-4186-4fdd-b0c5-e840cc300d73

The open-access MAF lists 171 somatic variants for this specimen: 128 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 39, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 2, RNA 2, Splice Site 1, Intron 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs760959587, COSV99681647; called by muse, mutect2, varscan2
- ACTBL2 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.29); catalogued as rs142178628; called by muse, mutect2, varscan2
- ADAMTS13 | c.2608C>T p.H870Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100747116; called by muse, mutect2, varscan2
- AEN | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.181); catalogued as rs1305179709, COSV100237488; called by muse, mutect2, varscan2
- AGO2 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99595882; called by muse, mutect2, varscan2
- AHNAK | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV99947968; called by muse, mutect2, varscan2
- AKAP12 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV99483621; called by muse, mutect2, varscan2
- ALYREF | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100485859; called by muse, mutect2, varscan2
- ANK3 | c.3559G>A p.E1187K (on ENST00000280772 / NM_001320874.2; = p.E321K on NM_001149.3) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV55068129; called by muse, mutect2, varscan2
- APBB1IP | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100770903, COSV63076294, COSV63076346; called by muse, mutect2, varscan2
- APOBR | c.3154G>A p.D1052N (on ENST00000431282; = p.D1061N on NM_018690.4) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV100112640; called by muse, mutect2, varscan2
- ARHGAP35 | c.4302C>G p.F1434L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV101351211; called by muse, mutect2, varscan2
- ARID1A | c.6806C>G p.S2269* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100252068, COSV61371645, COSV61375637; called by muse, mutect2, varscan2
- ASAP1 | c.2812G>A p.D938N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV100727386; called by muse, mutect2, varscan2
- ASIC2 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860355; called by muse, mutect2, varscan2
- ATG2B | c.3694C>G p.P1232A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99952094; called by muse, mutect2, varscan2
- ATP10D | c.2463G>A p.M821I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV99905729; called by muse, mutect2, varscan2
- ATP13A5 | c.2193G>C p.K731N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100665273, COSV60867694; called by muse, mutect2, varscan2
- BIN1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs794727107, COSV52121833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCRL | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs974511157, COSV66477473; called by muse, mutect2, varscan2
- CDC42BPA | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV100505642; called by muse, mutect2, varscan2
- CELSR3 | c.8712G>C p.R2904S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99373811; called by muse, mutect2, varscan2
- CEP192 | c.6700C>T p.Q2234* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV58060587; called by muse, mutect2, varscan2
- CHST7 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99333011; called by muse, mutect2, varscan2
- CLASRP | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99672976; called by muse, mutect2, varscan2
- COL17A1 | c.4108G>A p.D1370N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV59823774; called by muse, mutect2, varscan2
- COL4A4 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.187); catalogued as COSV100307064; called by muse, mutect2, varscan2
- COL6A3 | c.7025G>A p.R2342Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.385); catalogued as rs369317566; called by muse, mutect2, varscan2
- CTDSP1 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV99812000; called by muse, mutect2, varscan2
- CYP27C1 | c.355T>A p.F119I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV100079888; called by muse, mutect2, varscan2
- DACT1 | c.1456C>G p.P486A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100241917; called by muse, mutect2, varscan2
- DDX24 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1311470963, COSV100427781; called by muse, mutect2, varscan2
- DHX40 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs2523376; called by muse, mutect2
- DKKL1 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV99678730; called by muse, mutect2
- DNAJC13 | c.6551C>T p.S2184L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV53453369; called by muse, mutect2, varscan2
- DOCK6 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.829); catalogued as COSV99371026; called by mutect2, varscan2
- DSG1 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99936134; called by muse, mutect2, varscan2
- ELL3 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100082608; called by muse, mutect2, varscan2
- EVI5 | c.2323G>A p.G775S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV64827626; called by muse, mutect2, varscan2
- FAM47C | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1556331961, COSV100792691; called by muse, mutect2, varscan2
- FANCM | c.4088C>G p.S1363C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99951163; called by muse, mutect2, varscan2
- FIP1L1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100184497; called by muse, mutect2, varscan2
- FRMD5 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101296603; called by muse, mutect2, varscan2
- GDPD2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100978649, COSV65532037; called by muse, mutect2, varscan2
- GNG7 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as rs1325024174, COSV101191204, COSV66287926; called by muse, mutect2, varscan2
- H2BC8 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.902); catalogued as rs760291254, COSV55126438, COSV99773271; called by muse, mutect2, varscan2
- HABP4 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV64515161; called by muse, varscan2
- IFT122 | c.3310G>A p.D1104N (on ENST00000348417 / NM_052989.3; = p.D1045N on NM_018262.4) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99959446; called by muse, mutect2, varscan2
- IKZF5 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100924746; called by muse, mutect2, varscan2
- ITGAD | c.3354C>G p.I1118M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99791412; called by muse, mutect2, varscan2
- KIAA1549 | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.058); catalogued as COSV99651045; called by muse, mutect2, varscan2
- KIAA1755 | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99642186, COSV99642597; called by muse, mutect2, varscan2
- KLRK1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV99555166; called by muse, mutect2, varscan2
- KMT2B | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs370754915; called by muse, mutect2, varscan2
- KRT84 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs146876431; called by muse, mutect2, varscan2
- KYAT3 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99556437; called by muse, mutect2, varscan2
- LAMB4 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99224405; called by muse, mutect2, varscan2
- LCNL1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1444555128, COSV99811910; called by muse, mutect2
- LPIN2 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858486; called by muse, mutect2, varscan2
- MACF1 | c.11163G>C p.Q3721H (on ENST00000372915; = p.Q1654H on NM_012090.5) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99245079; called by muse, mutect2
- MAML2 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101594136, COSV101594165; called by muse, mutect2, varscan2
- MCM7 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV57996324; called by muse, mutect2, varscan2
- MMAB | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs573706523, COSV99904552; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.3376G>C p.E1126Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99820367; called by muse, mutect2, varscan2
- MYLK | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60611734; called by muse, mutect2, varscan2
- MYO7B | c.2929G>T p.A977S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.604); catalogued as COSV101268241; called by muse, mutect2, varscan2
- NOXRED1 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100033124; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP214 | c.2606A>G p.N869S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); catalogued as rs750052303, COSV100845307; called by muse, mutect2, varscan2
- NYAP2 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99796615, COSV99797080, COSV99798180; called by muse, mutect2, varscan2
- OCRL | c.617T>C p.M206T | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100843471; called by muse, mutect2, varscan2
- P2RY8 | c.783C>G p.I261M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101184058, COSV67176705, COSV67176831; called by muse, mutect2, varscan2
- PAPOLB | c.1451T>C p.I484T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101271464; called by muse, mutect2, varscan2
- PCBP3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101234325; called by muse, mutect2, varscan2
- PCDHGA1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV65298566; called by muse, mutect2, varscan2
- PCDHGA8 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99540220; called by muse, mutect2, varscan2
- PLEKHG2 | c.1370G>T p.R457I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV99217608; called by muse, mutect2, varscan2
- PPEF2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752432516, COSV99714629; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs146650273; called by pindel, varscan2
- PUS7 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV100708567; called by muse, mutect2, varscan2
- R3HDM1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99926352; called by muse, mutect2, varscan2
- RBM19 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV55692264; called by muse, mutect2
- RBM47 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs752100792, COSV55934734, COSV99920950; called by muse, mutect2, varscan2
- RBM7 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100348384; called by muse, mutect2, varscan2
- RYR2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs751428303, COSV63688268, COSV63692084; called by muse, mutect2, varscan2
- SIX3 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV99578424; called by muse, mutect2, varscan2
- SLC35A1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101060075; called by muse, mutect2, varscan2
- SLC35D3 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV100090563; called by muse, mutect2, varscan2
- SMARCA4 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60785665; called by muse, mutect2, varscan2
- SNX30 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100953889; called by muse, mutect2, varscan2
- SPATA46 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100723359; called by muse, mutect2, varscan2
- SPHKAP | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1264268232, COSV100764068; called by muse, mutect2, varscan2
- ST6GAL2 | c.623G>A p.W208* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100868023; called by muse, mutect2, varscan2
- STEAP3 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100713347; called by muse, mutect2, varscan2
- STOX2 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57852935; called by muse, mutect2, varscan2
- SV2A | c.1907G>C p.C636S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV100975179; called by muse, mutect2, varscan2
- SYNE1 | c.8972C>T p.T2991M (on ENST00000367255 / NM_182961.4; = p.T2998M on NM_033071.3) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs763526846, COSV55045961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACR1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100537957; called by muse, mutect2, varscan2
- TAF1L | c.3470C>T p.S1157L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99644856; called by muse, mutect2, varscan2
- TGM2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs372703574; called by muse, mutect2, varscan2
- TLL1 | c.1159-1G>A p.X387_splice | Splice Site (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99287651; called by muse, mutect2, varscan2
- TLN2 | c.4121C>T p.T1374I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100169271; called by muse, mutect2, varscan2
- TMED2 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV99147867; called by muse, mutect2, varscan2
- TMEM220 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs748517844, COSV59379436; called by muse, mutect2, varscan2
- TMEM62 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs1474127778, COSV99543694; called by muse, mutect2
- TP53BP1 | c.3952G>A p.G1318R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99780752; called by muse, mutect2, varscan2
- TP53BP2 | c.2714C>T p.S905F (on ENST00000343537 / NM_001031685.3; = p.S776F on NM_005426.2) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV100636681; called by muse, mutect2, varscan2
- TRAPPC11 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100591883, COSV58218061; called by muse, mutect2, varscan2
- TSPAN10 | c.142C>A p.L48M (on ENST00000574882 / NM_001290212.1; = p.L10M on NM_031945.4) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100148566; called by muse, mutect2, varscan2
- TUBGCP2 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs769462501, COSV99427892; called by muse, mutect2, varscan2
- VSIG4 | c.57C>T p.G19= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101038190; called by mutect2, varscan2
- WDFY3 | c.4880C>G p.S1627* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99883953; called by muse, mutect2, varscan2
- WDR1 | c.1589G>A p.G530E (on ENST00000382452; = p.G390E on NM_005112.5) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as COSV66725092; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZNF181 | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV101106301; called by muse, mutect2, varscan2
- ZNF214 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV99547462; called by muse, mutect2, varscan2
- ZNF267 | c.1745G>A p.S582N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100339815; called by muse, mutect2, varscan2
- ZNF646 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV100336714; called by muse, mutect2, varscan2
- ZNF782 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100001436; called by muse, mutect2, varscan2
- CCDC66 | c.2182_2183del p.E728Rfs*18 (on ENST00000394672 / NM_001353147.1; = p.E694Rfs*18 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by pindel, varscan2
- HERPUD1 | c.1130del p.F377Sfs*50 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1990dup p.C664Lfs*11 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- POLR2B | c.844dup p.R282Kfs*10 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- RGS12 | c.53del p.P18Qfs*31 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- ABCA1 | c.3166C>T p.L1056= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV101037132; called by muse, mutect2, varscan2
- ACSL4 | c.1839C>T p.I613= (on ENST00000340800 / NM_022977.2; = p.I572= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV100538661; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3510G>T p.L1170= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99719328; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.1995C>G p.L665= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV99783637; called by muse, mutect2, varscan2
- ARHGAP44 | c.1551G>C p.V517= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99310894; called by muse, mutect2, varscan2
- C3orf56 | c.171C>T p.L57= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV101228967, COSV67756468; called by muse, mutect2, varscan2
- CCDC74A | c.288G>A p.Q96= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV99723766; called by muse, mutect2, varscan2
- CDK18 | c.927G>A p.L309= (on ENST00000506784 / NM_212503.3; = p.L279= on NM_002596.4) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100774045, COSV63728196; called by muse, mutect2, varscan2
- DLGAP2 | c.1086C>T p.D362= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs758718171, COSV70099024; called by muse, mutect2, varscan2
- EHD1 | c.942C>T p.L314= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV57736706; called by muse, mutect2, varscan2
- EPCAM | c.699G>A p.L233= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99764202; called by muse, mutect2, varscan2
- FBXO38 | c.2040G>A p.Q680= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99693536; called by muse, mutect2, varscan2
- FKBP10 | c.1365C>T p.I455= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99505232; called by muse, mutect2, varscan2
- GNPTAB | c.2028G>A p.P676= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs192607073; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- GPIHBP1 | c.309G>A p.L103= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100427374; called by muse, mutect2, varscan2
- HCN4 | c.1279C>T p.L427= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99983866; called by muse, mutect2, varscan2
- HNRNPCL1 | c.576G>A p.Q192= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1320075698, COSV58616107; called by muse, mutect2, varscan2
- LHX3 | c.357C>G p.V119= (on ENST00000371748 / NM_178138.6; = p.V124= on NM_014564.5) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV65582203; called by muse, mutect2, varscan2
- MRM2 | c.117C>T p.L39= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2
- NPHP4 | c.2016C>T p.F672= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100976982; called by muse, mutect2, varscan2
- ONECUT2 | c.1098G>C p.G366= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV101529799; called by muse, mutect2, varscan2
- OTUD6A | c.750C>G p.V250= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100611018; called by muse, mutect2, varscan2
- PCDHGA4 | c.1287T>C p.Y429= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99540215; called by muse, mutect2, varscan2
- PIK3C2B | c.57C>T p.I19= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100915039, COSV65803818; called by muse, mutect2, varscan2
- PRPF8 | c.243C>T p.F81= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100517517; called by muse, mutect2, varscan2
- RALGAPA2 | c.4809C>T p.F1603= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99173807; called by muse, mutect2, varscan2
- RUVBL2 | c.489C>G p.L163= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs976563728, COSV99669061; called by muse, mutect2
- SIPA1L2 | c.3264C>T p.D1088= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs753002321, COSV99478654; called by muse, mutect2, varscan2
- SLC18A2 | c.951C>T p.I317= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV53693351; called by muse, mutect2, varscan2
- SLC18A2 | c.1227C>T p.L409= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs745949267, COSV53688674; called by muse, mutect2, varscan2
- SLC22A15 | c.408C>T p.F136= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs200436499, COSV65677649; called by muse, mutect2, varscan2
- SLC38A10 | c.525C>T p.H175= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs146728538, COSV55843207; called by muse, mutect2, varscan2
- SV2B | c.843C>T p.I281= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs374889788; called by muse, mutect2, varscan2
- TIMELESS | c.1320G>A p.L440= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99974061; called by muse, mutect2
- TNIP2 | c.502C>T p.L168= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100198683; called by muse, mutect2, varscan2
- TREML1 | c.103C>T p.L35= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100632705, COSV58294611; called by muse, mutect2, varscan2
- TUBA4A | c.540C>T p.A180= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs766444250, COSV99944822; called by muse, mutect2, varscan2
- UBASH3A | c.1800C>T p.L600= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs751231217, COSV52317710; called by muse, mutect2, varscan2
- UGT1A7 | c.795G>A p.V265= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV100692942, COSV60842547; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827593 C>G | 3'Flank (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- C8orf31 | n.359G>A | RNA (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20892G>A | Intron (SNP) | VAF 8/25 reads (32%) | catalogued as rs367792888; called by muse, mutect2, varscan2
- TCP10L3 | n.2610G>C | RNA (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100833019; called by muse, mutect2
